Surgical pathology report (de-identified scan), TCGA case TCGA-AG-3586, project TCGA-READ (Rectum Adenocarcinoma), tissue source site Indivumed, specimen TCGA-AG-3586-01A (Primary Tumor).

Diagnosis:

1.: Rectosigmoid colon shows a rectal carcinoma characterized histologically as a moderately differentiated, partially mucinous, colorectal adenocarcinoma, extending at most to within 3 cm of the aboral resection margin, with lymphatic tumor processes. Invasive tumor spread within all parietal layers of the intestine extending to the adjacent periproctical fatty tissue. Oral and aboral resection margin tumor-free.

Four periproctical or mesocolic lymph nodes with metastases of the rectal carcinoma spreading over the lymph node capsule in some cases. Other lymph nodes with non-characteristic reactive lesions.

2.: Mesocolic fatty tissue with signs of old necrotic lesions.

Tumor stage therefore pT3 pN2 (4/19) L0, V0; G2

Source: NCI Genomic Data Commons file 504494f8-11e4-43c4-ad81-68eb078c4065 (TCGA-AG-3586.DC14A03B-1593-4432-B4A0-914312897E60.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).